CCDI case PBCARS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/befb32a0-c2f5-4327-997f-dfb8324841f7

Demographics
Sex at birth: male.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 15.5 years (5,646 days).

Biospecimens (3 samples)
- Sample 0DMRAQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMRAY: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMRB6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
